Somatic mutation profile of tumor specimen MMRF_2545_1_BM_CD138pos (aliquot MMRF_2545_1_BM_CD138pos_T1_KHS5U_K15163) from MMRF case MMRF_2545, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,176 days).
Specimen MMRF_2545_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5ae3672-1fb4-45c2-adb3-1d2707d2cb21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2545_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2545_1_PB_Whole_C2_KHS5U_K15162; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89514a25-c000-44ec-ac66-c1f1add1fcbf

The open-access MAF lists 117 somatic variants for this specimen: 53 protein-altering or splice-affecting, 10 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 31, Intron 12, Silent 10, Nonsense Mutation 6, RNA 5, Frame Shift Del 2, 5'UTR 2, 5'Flank 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADIG | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs373626829; called by muse, mutect2, varscan2
- AGAP3 | c.757C>T p.R253* (on ENST00000622464; = p.R289* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 60/132 reads (45%) | catalogued as COSV58994596; called by muse, mutect2, varscan2
- AK5 | c.1550G>A p.R517H (on ENST00000354567 / NM_174858.3; = p.R491H on NM_012093.4) | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs771419630; called by muse, mutect2, varscan2
- ASXL3 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs772559746, COSV52475253; called by muse, mutect2, varscan2
- CHD6 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV58558587; called by muse, mutect2, varscan2
- CNTF | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100284360; called by muse, mutect2, varscan2
- DLC1 | c.2640C>A p.D880E (on ENST00000276297 / NM_001348081.2; = p.D443E on NM_006094.5) | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777534672, COSV99363330; called by muse, mutect2, varscan2
- DOHH | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 66/161 reads (41%) | catalogued as rs377662709; called by muse, varscan2
- ELAVL2 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56367836; called by muse, mutect2
- HTR1D | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371294680; called by muse, mutect2, varscan2
- MFGE8 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203147147; called by muse, mutect2, varscan2
- PCDHA6 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs782258872, COSV65341517; called by muse, mutect2, varscan2
- PIK3R1 | c.1550A>G p.N517S (on ENST00000521381 / NM_181523.3; = p.N247S on NM_181504.4) | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs1226481260; called by muse, mutect2
- RFLNA | c.644C>G p.T215R (on ENST00000546355 / NM_001365156.1; = p.T134R on NM_181709.4) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV58038703; called by muse, mutect2, varscan2
- RIT1 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 101/361 reads (28%) | catalogued as COSV64171910; called by muse, mutect2, varscan2
- SOX8 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469776275, COSV53511035; called by muse, mutect2, varscan2
- TMEM256 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1396527002; called by muse, mutect2, varscan2
- ZNF454 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 71/171 reads (42%) | catalogued as rs756892601, COSV100195260; called by muse, mutect2, varscan2
- ANKRD63 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- ASPHD1 | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ATAD5 | c.1784G>C p.R595T | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CHD2 | c.4176_4177del p.K1393Efs*15 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by mutect2, pindel, varscan2
- CUBN | c.2737A>T p.S913C | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DCT | c.1259A>T p.E420V | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- DHX9 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.116); called by muse, mutect2
- EFL1 | c.2960G>A p.C987Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM71B | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 104/220 reads (47%) | called by muse, mutect2, varscan2
- FAT3 | c.8329C>G p.P2777A | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FOXL1 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR179 | c.1123G>T p.V375L (on ENST00000621958; = p.V374L on NM_001004334.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- HMCN1 | c.8327A>T p.N2776I | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL4 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LARP4 | c.2030C>G p.S677C | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCOLN3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MROH1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MSLNL | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- NBEA | c.4084T>G p.S1362A | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- PCLO | c.6017A>T p.K2006I | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLE | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PSD3 | c.3038C>A p.P1013H (on ENST00000440756; = p.P1012H on NM_015310.4) | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RFX8 | c.629T>C p.V210A (on ENST00000646446; = p.V139A on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- SLC40A1 | c.1496T>G p.M499R | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC44A5 | c.1218A>G p.I406M | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC4A1AP | c.377del p.G126Vfs*44 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel
- SLC7A11 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SMARCA5 | c.311A>G p.H104R | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- TEK | c.2050C>A p.H684N | Missense Mutation (SNP) | VAF 8/230 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.649); called by muse, mutect2
- TIGD4 | c.306T>A p.N102K | Missense Mutation (SNP) | VAF 98/223 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TKFC | c.1514A>G p.E505G | Missense Mutation (SNP) | VAF 100/181 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TOMM22 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TRAPPC10 | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VPS35L | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- ZBTB18 | c.209T>G p.V70G | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARHGEF10L | c.1305C>G p.L435= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- CHST1 | c.540C>T p.D180= | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP3B | c.1926C>A p.T642= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2
- DSG4 | c.1830T>A p.G610= | Silent (SNP) | VAF 66/138 reads (48%) | catalogued as rs1338902586; called by muse, mutect2, varscan2
- GRIN2B | c.4008C>T p.Y1336= | Silent (SNP) | VAF 62/81 reads (77%) | catalogued as rs764080484, COSV74206890, COSV99078307; called by muse, mutect2, varscan2
- PPFIA3 | c.2757C>T p.N919= | Silent (SNP) | VAF 91/193 reads (47%) | called by muse, mutect2, varscan2
- SERPINB12 | c.519C>G p.L173= | Silent (SNP) | VAF 62/154 reads (40%) | called by muse, mutect2, varscan2
- SNED1 | c.1125C>T p.C375= | Silent (SNP) | VAF 7/125 reads (6%) | catalogued as rs1173949099, COSV60023639; called by muse, mutect2
- TLE6 | c.1128C>T p.P376= (on ENST00000246112 / NM_001143986.2; = p.P253= on NM_024760.3) | Silent (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- WIPF2 | c.360T>A p.A120= | Silent (SNP) | VAF 63/125 reads (50%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.1629+987G>A | Intron (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- AQP12B | chr2:240686456 T>G | 5'Flank (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- C19orf25 | c.131-27del | Intron (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel*, varscan2
- C21orf91 | c.*2031G>A | 3'UTR (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- C6orf201 | c.*69T>A | 3'UTR (SNP) | VAF 149/362 reads (41%) | catalogued as rs1480934776; called by muse, mutect2, varscan2
- CACNA1C | c.3828+96G>A | Intron (SNP) | VAF 52/73 reads (71%) | catalogued as COSV59695540; called by muse, mutect2, varscan2
- CASS4 | chr20:56459450 C>T | 3'Flank (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- CCDC184 | c.-124G>A | 5'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, varscan2
- CDHR1 | c.*2435G>T | 3'UTR (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- CHSY1 | c.*257A>T | 3'UTR (SNP) | VAF 41/82 reads (50%) | catalogued as rs558113670, COSV99574187; called by muse, mutect2, varscan2
- CYFIP2 | c.666+120T>A | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- DIPK1B | c.199-125G>A | Intron (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
- DLX4 | c.284-34C>A | Intron (SNP) | VAF 92/201 reads (46%) | called by muse, mutect2, varscan2
- DNTTIP2 | c.72+130G>A | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- FAM20B | c.*442_*463del | 3'UTR (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- FGF11 | c.*1580G>A | 3'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.160C>T | RNA (SNP) | VAF 82/189 reads (43%) | called by muse, mutect2, varscan2
- GABRR3 | c.907+67G>T | Intron (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- GSN-AS1 | n.3369C>A | RNA (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- HGSNAT | c.*2270T>G | 3'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- HHIP | c.*930T>C | 3'UTR (SNP) | VAF 45/97 reads (46%) | catalogued as rs561059407; called by muse, mutect2, varscan2
- HOXD1 | c.-28G>A | 5'UTR (SNP) | VAF 73/125 reads (58%) | called by muse, mutect2, varscan2
- JMJD6 | c.941+446G>C | Intron (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- KCNJ5 | chr11:128919762 A>T | 3'Flank (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- KLF11 | c.*283C>A | 3'UTR (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- LIN28B | c.*626C>A | 3'UTR (SNP) | VAF 22/62 reads (35%) | catalogued as COSV61493693; called by muse, mutect2, varscan2
- LRATD2 | c.*2860G>T | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- MEOX2 | c.*1147G>A | 3'UTR (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- MMP16 | c.*8647A>T | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- MTFMT | c.*34T>C | 3'UTR (SNP) | VAF 39/165 reads (24%) | called by muse, mutect2, varscan2
- MYCL | c.*1056G>A | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- OR51F5P | n.992G>A | RNA (SNP) | VAF 10/71 reads (14%) | catalogued as rs917567689; called by muse, mutect2, varscan2
- PANK3 | c.*8910A>G | 3'UTR (SNP) | VAF 5/148 reads (3%) | called by muse, mutect2
- PDE1B | c.114-5454C>T | Intron (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- PELP1 | c.1068+72T>C | Intron (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- PHPT1 | c.*53C>T | 3'UTR (SNP) | VAF 89/165 reads (54%) | called by muse, mutect2, varscan2
- PKD1L2 | n.3212C>T | RNA (SNP) | VAF 72/161 reads (45%) | catalogued as rs371035139; called by muse, mutect2, varscan2
- PPARGC1A | c.*3225T>C | 3'UTR (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- PPP2R2B | c.*1441C>T | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- RANGAP1 | c.*892T>C | 3'UTR (SNP) | VAF 71/196 reads (36%) | called by muse, mutect2, varscan2
- RBM19 | c.*9C>T | 3'UTR (SNP) | VAF 43/95 reads (45%) | catalogued as rs759837749, COSV55696373; called by muse, mutect2, varscan2
- RHBG | c.*235del | 3'UTR (DEL) | VAF 24/84 reads (29%) | called by muse*, pindel
- SMAD2 | c.*6555dup | 3'UTR (INS) | VAF 12/70 reads (17%) | catalogued as rs1568022412; called by mutect2, varscan2
- SOX11 | c.*401G>T | 3'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- STK19 | c.430+31C>G | Intron (SNP) | VAF 55/147 reads (37%) | called by muse, mutect2, varscan2
- TLR10 | c.*683T>C | 3'UTR (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- TMEM181 | c.*2998G>T | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- TMEM222 | c.*667C>G | 3'UTR (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- TMEM99 | n.766T>C | RNA (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- TSPYL4 | chr6:116258726 G>A | 5'Flank (SNP) | VAF 25/52 reads (48%) | catalogued as rs774550868, COSV101319474; called by muse, mutect2, varscan2
- ZFHX3 | c.*2358T>C | 3'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- ZFP90 | c.*5C>A | 3'UTR (SNP) | VAF 20/53 reads (38%) | catalogued as COSV68051480; called by muse, mutect2, varscan2
- ZFX | c.*4225G>A | 3'UTR (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- ZKSCAN5 | c.*316del | 3'UTR (DEL) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
